Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5430, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5430-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS

- (A) WIDEFIELD LARYNGECTOMY, PARTIAL PHARYNGECTOMY AND RIGHT HEMITHYROIDECTOMY:
INVASIVE SQUAMOUS CARCINOMA GRADE 3, 3 CM IN THICKNESS IN PYRIFORM SINUS INVOLVING RIGHT ARYEPIGLOTTIC FOLD, RIGHT FALSE VOCAL CORD. Presence of lymphatic and perineural invasion.
METASTATIC SQUAMOUS CARCINOMA IN 2 OF 2 LYMPH NODES WITH EXTRANODAL EXTENSION (SIZE OF METASTASIS 2.1 CM).
Thyroid gland with chronic inflammation, no tumor present.
- (B) ADDITIONAL LEVEL 2, LEFT LYMPH NODE:
Six lymph nodes, no tumor.
- (C) ADDITIONAL LEVEL 2, RIGHT LYMPH NODE:
One lymph node, no tumor.
- (D) POSTERIOR CRICOID MARGIN:
Squamous mucosa, no tumor present.
- (E) RIGHT PHARYNGEAL MARGIN:
Squamous mucosa, no tumor present.
- (F) LEFT PHARYNGEAL WALL:
Squamous mucosa, no tumor present.
- (G) RIGHT GLOSSOPHARYNGEAL SULCUS:
SQUAMOUS CARCINOMA IN SITU WITH AREA SUGGESTIVE OF MICROINVASION.
- (H) RIGHT SUBMUCOSAL MARGIN:
Skeletal muscle, no tumor present.
- (I) TOOTH:
Gross only.
- (J) RE-EXCISION RIGHT GLOSSOPHARYNGEAL SULCUS:
CARCINOMA IN SITU WITH AN AREA SUGGESTIVE OF SUPERFICIAL INVASION.
- (K) NEW RIGHT SUPERIOR GLOSSOPHARYNGEAL SULCUS MARGIN:
SQUAMOUS CARCINOMA IN SITU WITH AREAS OF SUGGESTIVE OF MICROINVASION.
- (L) NEW RIGHT INFERIOR GLOSSOPHARYNGEAL MARGIN:
SQUAMOUS CARCINOMA WITH MODERATELY DYSPLASIA.
- (M) LEFT POSTERIOR PHARYNGEAL MARGIN:
Squamous mucosa, no tumor present.

(A) WIDEFIELD LARYNGECTOMY, PARTIAL PHARYNGECTOMY AND RIGHT HEMITHYROIDECTOMY - A larynx (9.0 x 3.5 x 3.0 cm) and a portion of the pharynx. The attached hyoid bone measures 9.0 x 0.8 x 0.4 cm. The right thyroid lobe is also noted measuring 4.5 x 2.0 x 1.5 cm.

[page 2 of 3]
[REDACTED]

An ulcerated, firm, gray-tan tumor (3.0 x 2.5 x 2.0 cm) and its epicenter in the right pyriform sinus with involvement of the right aryepiglottic fold. The tumor does not appear to invade the underlying thyroid cartilage. The anterior epiglottic space is free of tumor. The thyroid shows a homogeneously brown cut surface without any discrete lesions.

The attached right neck dissection measures 9.0 x 12.0 x 2.3 cm and contains matted, positive lymph nodes measuring 4.5 x 3.0 x 3.0 cm. Representative sections are taken and submitted in three cassettes as follows:

The specimen is sent to the bone lab for decalcification.

SECTION CODE: A1, A2, one lymph node bisected; A3, A4, one lymph node bisected; A5-A16, tumor sequentially submitted from right; A17, right cords; A18, anterior commissure; A19, left cord; A20, anterior soft tissue margin; A21, anterior epiglottic space; A22, A23, thyroid. [REDACTED]

(B) ADDITIONAL LEVEL 2, LEFT LYMPH NODES - Fragment of pink-yellow tissue (2.0 x 1.4 x 0.3 cm). B1, 1 lymph node; B2, 2 lymph nodes; B3, 2 lymph nodes. [REDACTED]

(C) ADDITIONAL LEVEL 2, RIGHT LYMPH NODES - A pink-tan lymph node (2.2 x 0.8 x 0.6 cm). C, submitted in toto. [REDACTED]

(D) POSTERIOR CRICOID MUCOSA - One pink-tan strip of mucosa 1.9 cm in length. In toto, frozen section. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA AND UNDERLYING SOFT TISSUE, NO TUMOR PRESENT. [REDACTED]

(E) RIGHT PHARYNGEAL MARGIN - A pink-tan strip of mucosa 1.5 cm in length. In toto, frozen section. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(F) LEFT PHARYNGEAL MARGIN - A 2.5 cm long strip of mucosa in toto, frozen section. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA AND UNDERLYING SOFT TISSUE, NO TUMOR PRESENT. [REDACTED]

(G) RIGHT GLOSSOPHARYNGEAL SULCUS - A strip of mucosa (1.5 x 0.2 x 0.2 cm). In toto for frozen section. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, IN SITU, WITH AREAS STRONGLY SUGGESTIVE OF SUPERFICIAL INVASION. [REDACTED]

(H) RIGHT SUBMUCOSAL MARGIN - An ovoid portion of skeletal muscle (2.5 x 0.8 x 0.4 cm). Bisected along the long axis and entirely submitted for frozen section. [REDACTED]

[REDACTED]

(I) TOOTH - Received is one tooth (2.4 x 0.9 x 0.9 cm) with a gold filling. No microscopic sections taken. [REDACTED]

(J) REEXCISION OF RIGHT GLOSSOPHARYNGEAL SULCUS - A strip of pink-tan mucosa (2.0 cm in length and 0.3 cm in thickness) which is submitted entirely in J for frozen section. [REDACTED]

[page 3 of 3]
[REDACTED]

*FS/DX: CARCINOMA IN SITU, FOCAL, SUPERFICIAL INVASION CANNOT BE EXCLUDED. [REDACTED]

(K) NEW RIGHT SUPERIOR GLOSSOPHARYNGEAL SULCUS - A pink-tan strip of mucosa measuring 1.8 x 0.2 x 0.2 cm. Submitted in toto, K for frozen section. [REDACTED]

*FS/DX: SQUAMOUS CARCINOMA IN SITU. FOCAL SUPERFICIAL INVASION CANNOT BE EXCLUDED. [REDACTED]

(L) NEW RIGHT INFERIOR GLOSSOPHARYNGEAL SULCUS - A pink-tan strip of mucosa measuring 1.3 x 0.2 x 0.2 cm. Submitted in toto, L. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA WITH FOCAL MODERATE DYSPLASIA. [REDACTED]

(M) LEFT POSTERIOR PHARYNX - A pink-tan tissue fragment (4.5 x 1.0 x 0.6 cm). SECTION CODE: M, submitted in toto. [REDACTED]

Source: NCI Genomic Data Commons file 19f6afec-9aeb-4efe-9cb7-ecbfc5e7a1b5 (TCGA-CV-5430.B676F7D0-5E6A-4D38-A429-E0BA5D6C1677.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).